Somatic mutation profile of tumor specimen TCGA-TQ-A7RV-01A (aliquot TCGA-TQ-A7RV-01A-21D-A34A-08) from TCGA case TCGA-TQ-A7RV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.8 years (10,167 days).
Specimen TCGA-TQ-A7RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eace63d4-3cb9-4814-8116-d51fa0acb782.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RV-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RV-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d58929a-5703-4b69-8a74-1f914dca52dc

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Del 3, Silent 2, Splice Site 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 40/101 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- REEP1 | c.105+1G>A p.X35_splice | Splice Site (SNP) | VAF 97/286 reads (34%) | catalogued as rs1064797257, COSV99382387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 42/81 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EFEMP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816721, COSV62615383; called by muse, mutect2, varscan2
- FAM114A1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV100729135, COSV100729270; called by muse, mutect2
- LCK | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100287395; called by muse, mutect2, varscan2
- LMBRD2 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | catalogued as COSV99682541; called by muse, mutect2
- MCM10 | c.829C>G p.L277V (on ENST00000484800 / NM_182751.3; = p.L276V on NM_018518.5) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV101097899; called by muse, mutect2, varscan2
- PCDHGA12 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as COSV52749424; called by muse, mutect2
- SMARCA4 | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759118, COSV60790558; called by muse, mutect2
- TGFBRAP1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV99304676; called by muse, mutect2, varscan2
- TRAF3IP1 | c.771del p.E258Rfs*5 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs776957067; called by mutect2, pindel, varscan2
- ZNF276 | c.1342G>A p.A448T (on ENST00000443381 / NM_001113525.2; = p.A373T on NM_152287.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs576654600, COSV57067701, COSV57070084; called by muse, mutect2, varscan2
- ATRX | c.2565_2566del p.H855Qfs*7 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | called by pindel, varscan2
- ZNF711 | c.1570_1571del p.M524Efs*6 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- MAST1 | c.1287C>T p.A429= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs775469424, COSV99262238; called by muse, mutect2, varscan2
- SLC1A4 | c.1128C>T p.T376= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs772986775, COSV99308762, COSV99308791; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109274 T>C | 5'Flank (SNP) | VAF 7/29 reads (24%) | catalogued as rs1264708481; called by muse, mutect2, varscan2
